Somatic mutation profile of tumor specimen TCGA-38-7271-01A (aliquot TCGA-38-7271-01A-11D-2036-08) from TCGA case TCGA-38-7271, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.4 years (26,440 days).
Specimen TCGA-38-7271-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e65fc432-29d8-46b0-b083-84b673f70630.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-7271-11A (Solid Tissue Normal), aliquot TCGA-38-7271-11A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2adbac87-1656-4f60-b224-b10feef293ec

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 34, Silent 12, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1309G>T p.G437* (on ENST00000281708 / NM_001349798.2; = p.G357* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 16/163 reads (10%) | hotspot (GDC flag); catalogued as COSV55892346, COSV55927454; called by muse, mutect2
- ADCY1 | c.1899-2A>C p.X633_splice | Splice Site (SNP) | VAF 4/80 reads (5%) | catalogued as COSV99813116; called by muse, mutect2
- ADCY1 | c.1899-1G>A p.X633_splice | Splice Site (SNP) | VAF 4/80 reads (5%) | catalogued as COSV99812516, COSV99813117; called by muse, mutect2
- BIRC6 | c.14326G>T p.D4776Y | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101428093, COSV101429300; called by muse, mutect2, varscan2
- CAVIN4 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV56867589; called by muse, mutect2
- CNTNAP1 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52851977; called by muse, mutect2
- CREB5 | c.353G>T p.S118I (on ENST00000357727 / NM_182898.4; = p.S111I on NM_004904.3) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV63223885; called by mutect2, varscan2
- DDX42 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.622); catalogued as COSV63789304, COSV63790576; called by muse, mutect2
- EYA2 | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57946349; called by muse, mutect2, varscan2
- FDPS | c.964G>C p.G322R | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52740971, COSV99429591; called by muse, mutect2
- GABRQ | c.481C>G p.R161G | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV64782116, COSV64782717; called by mutect2, varscan2
- GDPD2 | c.209+1G>T p.X70_splice | Splice Site (SNP) | VAF 10/166 reads (6%) | catalogued as COSV100978731; called by muse, mutect2
- GOLGA2 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.301); catalogued as COSV70168536; called by muse, mutect2
- HERC1 | c.10236G>T p.M3412I | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV71248743; called by muse, mutect2, varscan2
- HIPK1 | c.2068C>G p.Q690E | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61246682, COSV61248951; called by muse, mutect2
- KRTAP19-4 | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV61858130, COSV61859138; called by muse, mutect2
- LRP1B | c.9670G>T p.E3224* | Nonsense Mutation (SNP) | VAF 7/136 reads (5%) | catalogued as COSV101262167; called by muse, mutect2
- MAMLD1 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs782607782, COSV53377475; called by muse, mutect2
- MUC16 | c.33202G>C p.E11068Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as COSV67474530, COSV67477058; called by muse, mutect2
- MYH7 | c.935T>A p.F312Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as CM042406, COSV62520973; called by muse, mutect2
- MYO1C | c.1690G>T p.D564Y (on ENST00000648651 / NM_001080779.2; = p.D529Y on NM_033375.5) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62999870; called by muse, mutect2
- MYOCD | c.1237C>A p.P413T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV58506742; called by muse, mutect2
- NPTN | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV54738266; called by muse, mutect2
- OR6F1 | c.551G>T p.W184L | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.657); catalogued as COSV100129524; called by muse, mutect2
- PCDH15 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57408645; called by muse, mutect2
- PFKFB1 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 8/79 reads (10%) | PolyPhen benign (0); catalogued as COSV66628799; called by muse, mutect2
- PLCD4 | c.1872C>G p.F624L | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV68744388; called by muse, mutect2
- PPP2R5D | c.453G>C p.E151D | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV57840734; called by muse, mutect2
- QRICH1 | c.922A>T p.T308S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.628); catalogued as COSV62616379; called by muse, mutect2, varscan2
- RARA | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as COSV54196503; called by muse, mutect2
- SFMBT2 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.212); catalogued as COSV100739778; called by muse, mutect2
- SLC39A4 | c.1756G>A p.E586K (on ENST00000301305 / NM_001374839.1; = p.E561K on NM_017767.3) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.778); catalogued as rs1554871932, COSV52779687; called by muse, mutect2
- SPANXN3 | c.123G>C p.L41F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs782340428, COSV65140533; called by muse, mutect2, varscan2
- STK26 | c.1171del p.A391Pfs*10 | Frame Shift Del (DEL) | VAF 12/116 reads (10%) | catalogued as COSV53747061; called by mutect2, varscan2
- SV2C | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV100456970; called by muse, mutect2
- TESMIN | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54833663; called by muse, mutect2
- VCAN | c.4469C>A p.S1490* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV54109151; called by muse, mutect2, varscan2
- ZFP36L1 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 9/137 reads (7%) | catalogued as COSV60544191, COSV60544799; called by muse, mutect2
- ZMYM3 | c.2165C>A p.A722E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV58738990; called by muse, mutect2
- ZNF527 | c.1277G>C p.R426P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.275); catalogued as COSV62232058; called by muse, mutect2, varscan2
- ZNF627 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as rs1483648497, COSV63142463; called by muse, mutect2
- ZSCAN18 | c.1103del p.G368Efs*61 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as COSV53733254; called by mutect2, varscan2
- HEATR9 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- MYO1C | c.1688A>G p.N563S (on ENST00000648651 / NM_001080779.2; = p.N528S on NM_033375.5) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2
- ADM | c.351G>T p.V117= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99534417; called by muse, mutect2, varscan2
- CHST1 | c.763C>A p.R255= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as rs774865102, COSV57323906; called by muse, mutect2
- ELAPOR1 | c.2190C>T p.F730= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV64040717; called by muse, mutect2
- FCRL3 | c.582G>T p.L194= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV63843051; called by muse, mutect2
- HDAC4 | c.1548G>A p.R516= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as COSV61869217; called by muse, mutect2, varscan2
- NLRP7 | c.1395C>T p.S465= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV60176915; called by muse, mutect2
- RNF214 | c.1395C>T p.F465= | Silent (SNP) | VAF 8/248 reads (3%) | catalogued as COSV56119734; called by muse, mutect2
- SNTN | c.189T>A p.T63= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV59539137; called by muse, mutect2, varscan2
- TIMM44 | c.1173C>T p.I391= | Silent (SNP) | VAF 7/157 reads (4%) | catalogued as COSV54492717; called by muse, mutect2
- USP51 | c.489G>T p.R163= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV101540711; called by muse, mutect2
- UTP14A | c.549C>A p.P183= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100928945; called by muse, mutect2
- YY1AP1 | c.984C>T p.L328= (on ENST00000295566 / NM_139118.2; = p.L271= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as COSV55122694; called by muse, mutect2
